Somatic mutation profile of tumor specimen MP2PRT-PAPTLM-TMP1-A (aliquot MP2PRT-PAPTLM-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPTLM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (679 days).
Specimen MP2PRT-PAPTLM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49183612-a879-4050-ae7a-664131a2a240.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPTLM-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPTLM-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba4d6ec3-4093-45c8-8f90-c5492c21b112

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, Frame Shift Del 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHA3 | c.432C>A p.D144E | Missense Mutation (SNP) | VAF 186/477 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60698440; called by muse, mutect2, varscan2
- H1-5 | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 179/416 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58899462; called by muse, mutect2, varscan2
- RBM39 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 150/465 reads (32%) | catalogued as COSV53614445; called by muse, mutect2, varscan2
- TRAPPC12 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 201/560 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs761391430; called by muse, mutect2, varscan2
- DSP | c.2575A>G p.K859E | Missense Mutation (SNP) | VAF 165/402 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- WIF1 | c.457del p.D153Mfs*2 | Frame Shift Del (DEL) | VAF 186/514 reads (36%) | called by mutect2, pindel, varscan2
- EXPH5 | c.1824A>G p.V608= | Silent (SNP) | VAF 20/442 reads (5%) | catalogued as COSV56205549; called by muse, mutect2
- GGTLC1 | c.261C>T p.N87= | Silent (SNP) | VAF 18/377 reads (5%) | catalogued as rs143183217; called by muse, mutect2
- PHC1 | c.651T>C p.A217= | Silent (SNP) | VAF 140/335 reads (42%) | called by muse, mutect2, varscan2
- FCSK | c.235-40G>T | Intron (SNP) | VAF 18/618 reads (3%) | called by muse, mutect2
